Gene-level copy-number profile of tumor specimen TCGA-BA-5151-01A from TCGA case TCGA-BA-5151, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 72.7 years (26,569 days).
Specimen TCGA-BA-5151-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.93cb5743-3223-4310-933f-65500c54494c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-5151-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d86e2f30-6ec4-4aad-802f-0d1a29e8301a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,383; copy number 1: 1,912; copy number 2: 54,948; copy number 3: 999; copy number 9: 6; copy number 17: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-5151-01A-01D-1432-01): tumor purity 0.62, ploidy 4.11, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:111,394,875–111,411,883, 2 genes: AC003989.2, AC003989.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:25,312,774–27,282,225, 32 genes, copy number 9–17 (within-gene range 1–17): ZCCHC4, ANAPC4, AC133963.2, AC133963.1, AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357, AC097714.1, RBPJ, CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4, AC024132.2, AC024132.1, LINC02261, Y_RNA, AC024132.3.

Autosomal genes at a single copy (total copy number 1): 1,872. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
